Gene-level copy-number profile of tumor specimen TCGA-VQ-A8PH-01A from TCGA case TCGA-VQ-A8PH, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 62.8 years (22,940 days).
Specimen TCGA-VQ-A8PH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.19edefb0-efce-408c-bf24-e96bd951b608.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8PH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 851 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a3c93357-0b0d-46a1-b177-7f98d70d946c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 118; copy number 1: 315; copy number 2: 21,868; copy number 3: 23,389; copy number 4: 9,271; copy number 5: 381; copy number 6: 2,539; copy number 7: 780; copy number 8: 202; copy number 9: 229; copy number 10: 171; copy number 11: 269; copy number 13: 148; copy number 15: 64; copy number 17: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8PH-01A-12D-A40Z-01): tumor purity 0.52, ploidy 3.11, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 117 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:100,836,269–100,947,194, 1 gene (within-gene range 0–2): AL117190.1.
- chr14:100,874,493–101,335,497, 112 genes (broad region; genes not listed).
- chr16:61,638,233–62,037,035, 4 genes (within-gene range 0–2): AC092125.2, CDH8, AC092125.1, RN7SKP76.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,891 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,151,586–160,954,809, 35 genes, copy number 8 (within-gene range 3–8): ATP1A4, CASQ1, AL121987.2, PEA15, DCAF8, AL139011.2, AL139011.1, RPSAP18, PEX19, COPA, SUMO1P3, Y_RNA, NCSTN, NHLH1, RNU4-42P, VANGL2, SLAMF6, AL138930.1, CD84, SLAMF1, SETP9, AL121985.1, CD48, SLAMF7, AL121985.3, AL121985.2, LY9, CD244, PPIAP37, ITLN1, AL354714.2, AL354714.3, AL354714.1, AL354714.4, ITLN2.
- chr1:182,899,865–183,472,265, 14 genes, copy number 8–9: SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P, LAMC1, LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1.
- chr2:84,821,650–86,912,978, 75 genes, copy number 7–11 (within-gene range 4–11) (broad region; genes not listed).
- chr2:113,022,089–113,134,016, 5 genes, copy number 8: IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN.
- chr3:52,287,089–52,897,562, 39 genes, copy number 7 (within-gene range 3–7): GLYCTK, GLYCTK-AS1, MIR135A1, DNAH1, PPP2R5CP, BAP1, PHF7, SEMA3G, TNNC1, NISCH, STAB1, NT5DC2, SMIM4, PBRM1, RNU6-856P, RNU6ATAC16P, GNL3, AC104446.3, AC104446.1, SNORD19, SNORD19B, SNORD19C, SNORD69, GLT8D1, SPCS1, NEK4, AC104446.2, AC006254.2, AC006254.3, ITIH1, ITIH3, ITIH4, AC006254.1, ITIH4-AS1, MUSTN1, STIMATE-MUSTN1, STIMATE, MIR8064, AC099667.1.
- chr7:1,428,465–27,662,883, 446 genes, copy number 7–10 (broad region; genes not listed).
- chr7:51,716,657–54,571,080, 26 genes, copy number 7 (within-gene range 6–7): RN7SL292P, AC006478.1, AC006478.2, AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A.
- chr7:79,768,028–80,312,456, 5 genes, copy number 7 (within-gene range 3–7): GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1.
- chr7:85,636,013–99,325,826, 205 genes, copy number 7–10 (broad region; genes not listed).
- chr7:146,116,002–148,420,998, 1 gene, copy number 7 (within-gene range 3–7): CNTNAP2.
- chr7:146,311,720–147,378,121, 5 genes, copy number 7: Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4.
- chr8:94,487,689–95,811,254, 34 genes, copy number 9 (within-gene range 6–9): VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8, CCNE2, AC087752.4, AC087752.1, NDUFAF6, TP53INP1, AC087752.3, AC087752.2, AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2, C8orf37-AS1, LINC01298, C8orf37, AC024995.1, AC083836.1.
- chr8:97,772,313–97,853,013, 3 genes, copy number 8 (within-gene range 6–8): Y_RNA, LAPTM4B, AP003357.1.
- chr12:57,095,408–57,959,148, 58 genes, copy number 9 (within-gene range 4–9): STAT6, LRP1, LRP1-AS, MIR1228, NXPH4, AC137834.2, SHMT2, NDUFA4L2, STAC3, AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG.
- chr13:73,100,575–73,408,352, 6 genes, copy number 7: FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12.
- chr13:86,909,586–87,458,407, 5 genes, copy number 7 (within-gene range 3–7): LINC00430, UBBP5, LIN28AP2, AL360267.2, AL360267.1.
- chr13:107,788,342–107,933,503, 3 genes, copy number 7: FAM155A-IT1, AL359436.1, AL136964.1.
- chr15:79,141,939–81,755,217, 70 genes, copy number 9–13 (within-gene range 4–13) (broad region; genes not listed).
- chr15:89,243,945–101,078,257, 284 genes, copy number 8–17 (within-gene range 2–17) (broad region; genes not listed).
- chr17:39,757,718–40,475,289, 39 genes, copy number 7–11 (within-gene range 4–11): IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1.
- chr20:31,514,410–35,557,634, 151 genes, copy number 10 (broad region; genes not listed).
- chr20:37,619,298–38,772,520, 41 genes, copy number 8: LINC00489, AL162293.1, CTNNBL1, VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173.
- chr20:39,213,777–54,859,812, 341 genes, copy number 8–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 276. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
